Somatic mutation profile of tumor specimen MMRF_1424_1_BM_CD138pos (aliquot MMRF_1424_1_BM_CD138pos_T1_KAS5U_L01597) from MMRF case MMRF_1424, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.5 years (14,797 days).
Specimen MMRF_1424_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe3bebdb-b947-4e47-bab9-d03306ba9ab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1424_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1424_1_PB_Whole_C2_KAS5U_L01606; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7f50c1-6c79-435b-ad65-b6f0398d468e

The open-access MAF lists 113 somatic variants for this specimen: 49 protein-altering or splice-affecting, 9 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 32, Intron 11, Silent 9, 5'UTR 5, 5'Flank 3, Nonsense Mutation 3, 3'Flank 3, Frame Shift Del 2, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 54/60 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM4 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs866426141; called by muse, mutect2, varscan2
- DLC1 | c.1991C>T p.T664M (on ENST00000276297 / NM_001348081.2; = p.T227M on NM_006094.5) | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs760883329, COSV99364929; called by muse, mutect2, varscan2
- EFCAB12 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs1200136896; called by muse, mutect2, varscan2
- FCRL3 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1330611055; called by muse, mutect2
- IGLL5 | c.206+2T>G p.X69_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, mutect2, varscan2
- IGLV4-3 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1277642148; called by muse, mutect2, varscan2
- IL1RAPL1 | c.476G>C p.S159T | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.114); catalogued as COSV56282649; called by muse, mutect2, varscan2
- KCNQ2 | c.1666A>C p.K556Q (on ENST00000359125 / NM_172107.4; = p.K528Q on NM_004518.6) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1311203; called by muse, mutect2
- MACF1 | c.20436C>G p.F6812L (on ENST00000372915; = p.F4857L on NM_012090.5) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV57131646, COSV99243137; called by muse, mutect2, varscan2
- OLFM3 | c.320C>A p.T107N (on ENST00000338858 / NM_001288821.1; = p.T87N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV58801287; called by muse, mutect2, varscan2
- PLEKHM1 | c.2753T>C p.I918T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs767160296; called by muse, mutect2, varscan2
- PPHLN1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV56729033; called by muse, mutect2, varscan2
- PTPRM | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs769216825; called by muse, mutect2, varscan2
- SI | c.3323C>A p.S1108* | Nonsense Mutation (SNP) | VAF 53/297 reads (18%) | catalogued as COSV100017524, COSV52264546; called by muse, mutect2, varscan2
- SLC4A3 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs757973768, COSV99812925; called by muse, mutect2, varscan2
- SLC5A2 | c.1466T>A p.L489H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368364383; called by muse, mutect2, varscan2
- TEX13C | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1486724270, COSV65376312; called by muse, mutect2, varscan2
- TLE2 | c.1564G>A p.G522S | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs768649883; called by muse, mutect2, varscan2
- ADGRV1 | c.11327T>C p.L3776S | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AOX1 | c.1732G>C p.D578H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2
- APBA2 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ASB17 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CRLF1 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CSRNP2 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DNAH5 | c.6223C>A p.P2075T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DYSF | c.1884C>A p.C628* | Nonsense Mutation (SNP) | VAF 44/77 reads (57%) | called by muse, mutect2, varscan2
- FAM184A | c.3080_3083del p.N1027Tfs*33 | Frame Shift Del (DEL) | VAF 33/72 reads (46%) | called by mutect2, pindel, varscan2
- FANCM | c.2803A>T p.S935C | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- GRIP2 | c.632C>A p.T211N (on ENST00000619221; = p.T114N on NM_001080423.4) | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- HEPACAM | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 135/263 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KREMEN1 | c.1364A>C p.K455T (on ENST00000407188; = p.K457T on NM_032045.5) | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LARGE1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LRP1B | c.9872C>A p.A3291D | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MFSD1 | c.1176C>T p.F392= | Splice Region (SNP) | VAF 207/280 reads (74%) | called by muse, mutect2, varscan2
- MTERF4 | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NOP14 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- OR5L1 | c.381del p.C127* | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | called by mutect2, pindel, varscan2
- PCLO | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- PLAC1 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL2 | c.1246A>T p.I416L (on ENST00000615277 / NM_001144382.2; = p.I290L on NM_015184.5) | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PROM2 | c.2373C>A p.F791L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SRGAP3 | c.220T>C p.F74L | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- WBP1L | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLT2 | c.816C>A p.Y272* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ZNF568 | c.1761A>T p.E587D | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF648 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF69 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ZSCAN10 | c.496A>T p.S166C (on ENST00000252463; = p.S221C on NM_032805.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH8 | c.1449T>G p.A483= | Silent (SNP) | VAF 64/67 reads (96%) | called by muse, mutect2, varscan2
- CEP290 | c.3375T>C p.S1125= | Silent (SNP) | VAF 87/220 reads (40%) | called by muse, mutect2, varscan2
- CSDE1 | c.1281T>G p.R427= (on ENST00000358528 / NM_001007553.3; = p.R396= on NM_007158.6) | Silent (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- DNAH9 | c.7951C>T p.L2651= | Silent (SNP) | VAF 174/194 reads (90%) | catalogued as rs761200913; called by muse, mutect2, varscan2
- ENOX1 | c.1534C>T p.L512= | Silent (SNP) | VAF 98/110 reads (89%) | catalogued as rs558558464; called by muse, mutect2, varscan2
- SCARF2 | c.2523C>T p.T841= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs1361543218; called by muse, mutect2, varscan2
- SLC28A2 | c.1719T>C p.C573= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV61664499; called by muse, mutect2, varscan2
- UHRF1BP1L | c.223C>T p.L75= | Silent (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- ZNF324B | c.969G>T p.R323= | Silent (SNP) | VAF 17/37 reads (46%) | called by mutect2, varscan2
- ABCC9 | chr12:21801070 C>T | 3'Flank (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- ABCD4 | c.*945A>T | 3'UTR (SNP) | VAF 42/44 reads (95%) | called by muse, mutect2, varscan2
- AF241726.1 | c.172-444664dup | Intron (INS) | VAF 51/129 reads (40%) | catalogued as rs748384023; called by mutect2, pindel, varscan2
- ALPG | c.*25T>A | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2, varscan2
- ARPC5L | c.*190C>A | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- BCL7A | chr12:122021411 G>A | 5'Flank (SNP) | VAF 64/134 reads (48%) | catalogued as COSV55846921, COSV55847077; called by muse, mutect2, varscan2
- CARNMT1 | c.*276G>A | 3'UTR (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- CDR2L | c.*1450G>T | 3'UTR (SNP) | VAF 66/71 reads (93%) | called by muse, mutect2, varscan2
- CNNM4 | c.*1975C>T | 3'UTR (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- COL4A1 | c.*1398T>C | 3'UTR (SNP) | VAF 33/39 reads (85%) | called by muse, mutect2, varscan2
- CORO7 | c.158-109C>T | Intron (SNP) | VAF 61/111 reads (55%) | called by muse, mutect2, varscan2
- CPEB3 | c.*2614A>G | 3'UTR (SNP) | VAF 77/178 reads (43%) | catalogued as rs1191975113; called by muse, mutect2, varscan2
- DAP3 | chr1:155689068 G>T | 5'Flank (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.365+5598G>A | Intron (SNP) | VAF 66/153 reads (43%) | catalogued as rs1055782101; called by muse, mutect2, varscan2
- EDIL3 | c.*86A>G | 3'UTR (SNP) | VAF 87/200 reads (44%) | called by muse, mutect2, varscan2
- FAM135B | c.*422G>A | 3'UTR (SNP) | VAF 49/126 reads (39%) | catalogued as rs1277557905; called by muse, mutect2, varscan2
- FBXL4 | c.*196C>G | 3'UTR (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- FRG2C | c.*625C>A | 3'UTR (SNP) | VAF 42/120 reads (35%) | called by muse, varscan2
- HDX | c.*468A>C | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- HYDIN2 | n.1204A>T | RNA (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- IGSF9B | c.*10671C>T | 3'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- ITIH5 | c.2149+80C>T | Intron (SNP) | VAF 14/27 reads (52%) | catalogued as rs977268882; called by muse, mutect2, varscan2
- ITPRIP | c.*111G>T | 3'UTR (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- KCNV2 | c.-203G>T | 5'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- KIAA1958 | c.*9118A>G | 3'UTR (SNP) | VAF 71/119 reads (60%) | called by muse, mutect2, varscan2
- LRRTM4 | c.-196A>G | 5'UTR (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- MROH9 | c.-29G>A | 5'UTR (SNP) | VAF 187/404 reads (46%) | called by muse, mutect2, varscan2
- NEDD4L | c.1125+61G>A | Intron (SNP) | VAF 44/95 reads (46%) | catalogued as rs934625165; called by muse, mutect2, varscan2
- NOL4 | c.773-3981T>C | Intron (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- NRP1 | c.*1462T>C | 3'UTR (SNP) | VAF 74/157 reads (47%) | called by muse, mutect2, varscan2
- NUDCD3 | c.*919G>A | 3'UTR (SNP) | VAF 63/120 reads (53%) | called by muse, mutect2, varscan2
- OGT | chrX:71529822 G>T | 5'Flank (SNP) | VAF 145/283 reads (51%) | called by muse, mutect2, varscan2
- OOSP2 | c.243+41G>T | Intron (SNP) | VAF 55/112 reads (49%) | called by muse, mutect2, varscan2
- PAX6 | chr11:31789498 C>T | 3'Flank (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- PCDH11X | c.*3179A>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- PLXND1 | c.*706T>C | 3'UTR (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- POU2F1 | c.*6433A>C | 3'UTR (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
- PPFIA4 | c.*754C>A | 3'UTR (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- PRCC | c.1324-48T>C | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- RAB3C | c.*4963G>C | 3'UTR (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- RSU1 | c.-91C>T | 5'UTR (SNP) | VAF 48/99 reads (48%) | catalogued as rs373009474; called by muse, mutect2, varscan2
- SEMA3C | c.*2067C>A | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SEMA5A | c.*7774G>A | 3'UTR (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- SFXN5 | c.*1263G>A | 3'UTR (SNP) | VAF 81/168 reads (48%) | called by muse, mutect2, varscan2
- SLC12A1 | c.-373C>G | 5'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- SOX11 | c.*5033A>C | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- SOX2 | c.*819T>G | 3'UTR (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- SPOCK3 | c.*651T>G | 3'UTR (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- SV2C | c.*4796G>T | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- TARS1 | c.*289G>T | 3'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- TNRC18 | c.187+471C>T | Intron (SNP) | VAF 91/170 reads (54%) | called by muse, mutect2, varscan2
- TSN | c.66+443G>T | Intron (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- UBE2D3 | c.199-168del | Intron (DEL) | VAF 11/22 reads (50%) | called by mutect2, pindel, varscan2
- WNK2 | chr9:93318517 G>T | 3'Flank (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- ZFAND1 | c.*491A>G | 3'UTR (SNP) | VAF 57/121 reads (47%) | catalogued as rs1235798665; called by muse, mutect2, varscan2
